Somatic mutation profile of tumor specimen 0DRZIS from CCDI case PBCBNP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.5 years (3,823 days).
Specimen 0DRZIS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e75aac41-7147-4415-a740-3441de801343.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f6ea961-9f49-4394-8de3-a09c9d0879ea

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 26/988 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- TFAP2D | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 350/828 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
